Surgical pathology report (de-identified scan), TCGA case TCGA-56-8625, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8625-01A (Primary Tumor).

[page 1 of 5]
Surg Path Final Report

* Final Report *

*** Final Report ***

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

PROCEDURE

Biopsy.

SPECIMEN:

- A. Right lower lobe, frozen.
- B. Rt. middle lobe wedge check area with stitch.
- C. L9 lymph node.
- D. L10 lymph node.
- E. L8 lymph node.

HISTORY

Squamous cell cancer.

GROSS

A. Labeled "right lower lobe frozen" is a resected right lower lobe of pink-tan rubbery lung, 16.2 x 12.8 x 5.2 cm and 290 grams. There are multiple linear staple lines in the hilar area and one at the apex. Bronchial resection margin is taken for frozen section examination (FSA1).

Vessel resection margins in this area are submitted in block 4. Two centimeters from the bronchial resection margin, there is a 3.1 x 2.7 x 1.5 cm firm tan, partially necrotic tumor mass of the anteromedial segment, which encases and apparently obstructs the bronchus, as distal bronchi exude white pus-like material. A tumor appears to extend up to the large vessel wall, which is not occluded, and to involve adjacent peribronchial lymph node (blocks 5-7). Overlying pleura in this area is not grossly involved, but ragged and with staple lines impeding evaluation (block 8). Three black peribronchial lymph nodes contiguous with the mass appear partially involved by tumor and range from 0.6 to 1.2 cm in greatest dimension each (block 9-11, one node each).

A separate firm tan tumor mass involving the apex of the superior segment, is 3.5 cm away from the bronchial resection margin and 2.5 cm from the hilar tumor. It is ovoid, 4.2 x 2 x 2.6 cm, firm, tan-white and with elevated, well-defined margins. The tumor appears to involve disrupted parenchyma beneath the suture line in this area (frozen sections A2 and A3). According to the surgeon, this area corresponds to the area of lung parenchyma submitted for

[page 2 of 5]
Surg Path Final Report

* Final Report *

frozen section examination with surface inked black. Apex tumor blocks 12 and 13. Parenchyma away from these lesions displays dilated bronchi, though many filled with pus and tan-pink parenchyma without additional nodules (block 13). A portion of both tumors is submitted as separate specimens for the [REDACTED] [REDACTED]

B. Labeled "right middle lobe wedge, check area with stitch" is a 7.8 x 7.5 x 2.5 cm and 78 gram wedge of purple-tan lung with generally smooth pleural surface and a Y-shaped heavy staple line along one aspect. A stitch in the staple line denotes the area of special attention, which is the bronchial margin and submitted for frozen section evaluation. Next, additional section of this margin is taken as block 2. According to the surgeon, this area corresponds to the area of gross tumor at the apex of specimen "A." No gross tumor is seen in this area or elsewhere within the rubbery purple-tan parenchyma. Bronchi are opened and free of lesion. [REDACTED]

C. "L9 lymph node." A tan and red-brown piece of soft tissue is up to 9 mm in greatest diameter. [REDACTED]

D. "L10 lymph node." A tiny piece of darkish red-brown soft tissue is up to 3 mm across. [REDACTED]

E. "L8 lymph node." A reddish brown piece of soft tissue is up to 7 mm in greatest diameter, bisected. [REDACTED] [REDACTED]

FROZEN SECTION DIAGNOSIS

A1. Right lower lobectomy:

Bronchial resection margin, negative for carcinoma. Tumor 2 cm from bronchial resection margin. [REDACTED] Diagnosis to Dr. [REDACTED]

A2. Parenchymal margin of apex tumor:

Positive for carcinoma. [REDACTED]

B. Right middle lobectomy:

Bronchial resection margin, negative for carcinoma. [REDACTED]

MICROSCOPIC

A. The frozen section control block confirms the frozen section findings of a negative bronchial resection margin. The frozen section control of the apex tumor confirms that is a nonsmall cell carcinoma of high grade with foci of necrosis and apparent extensive invasion of vascular channels, probably lymphatics.

As noted grossly the large vein near the hilum and has infiltrating carcinoma in its wall and the associated artery is negative. The lymph node that is grossly involved near the hilum contains

[page 3 of 5]
Surg Path Final Report

* Final Report *

metastatic high-grade carcinoma. The tumor focally has squamous features and I do not see any small cell carcinoma, but part of the larger tumor by the hilum does have some smaller cell size, but appears to be a less mature form of squamous cell carcinoma. The tumor in blocks 12 and 13 from the apex has larger cells and more glassy cytoplasm and on H and E a question of additional adenocarcinoma is raised.

Out of all sampled lymph nodes we have four of six positive lymph nodes. The tumor grows immediately beneath the pleural surface, but does not present to the outer surface. Focal invasion into the pleura is noted.

Due to the multiple histologic morphologic variations in the tumors, selected blocks A7 and A13 from the hilar and apical foci are selected, respectively, for additional immunostains. P63 and CK 5, squamous markers, are strongly positive in both tumor nodules. TTF-1, a good marker for adenocarcinomas and small cell carcinoma is negative except for a few scattered cells. The stains were prepared at [REDACTED] and the controls work. These results indicate squamous cell carcinoma throughout both tumor nodules.

B. The frozen section control confirms the frozen section findings of a bronchial resection margin negative for tumor. Additional tissue from this specimen is processed and all is negative for invasive tumor.

C. The lymph node is negative for tumor.

D. The lymph node is reactive but is negative for metastatic tumor.

E. The lymph node is enlarged but is reactive, negative for metastatic disease. [REDACTED]

DIAGNOSIS

- A. Right middle lung lobe, resection with frozen sections:
Two foci of squamous cell carcinoma, poorly differentiated.
Hilar tumor 3.1 cm in diameter.
Apical tumor 4.2 cm in diameter.

Metastatic squamous cell carcinoma in four of six parabrachial lymph nodes.

- B. Right middle lung lobe, lobectomy:
Negative for carcinoma.

[page 4 of 5]
Surg Path Final Report

* Final Report *

C. L9 lymph node, biopsy:
Negative for carcinoma.

D. L 10 lymph node, biopsy:
Negative for carcinoma.

E. L8 lymph node, biopsy:
Negative for carcinoma.

SYNOPTIC REPORT - LUNG

SPECIMEN: Right lung..

SPECIMEN INTEGRITY: Intact.

TUMOR SITE: Lower lobe.

TUMOR SIZE: Hilar focus 3.1 cm, apical focus 4.2 cm.

TUMOR FOCALITY: Two foci.

HISTOLOGIC TYPE: Squamous cell carcinoma.

HISTOLOGIC GRADE: 3.

VISCERAL PLEURA INVASION: Yes.

MARGINS: Negative.

Bronchial margin: Neg.

Vascular margin: Neg.

Parenchymal margin: Neg.

Parietal pleural margin: Not sampled.

Chest wall margin: Not sampled.

Other attached tissue margin: Neg.

Distance of invasive carcinoma from closest margin: Less than
1 mm (free pleural surface).

VASCULAR INVASION: Extensive lymph vascular invasion.

LYMPH NODES: Four of six parabronchial nodes positive.

OTHER FINDINGS: Emphysema.

PATHOLOGICAL TNM (AJCC [REDACTED]):

TNM DESCRIPTORS: Multiple foci.

pT: 3.

pN: 1.

Completed Action List:

Source: NCI Genomic Data Commons file 88f1687b-9973-465d-9bab-4b7c92852187 (TCGA-56-8625.9BE086C9-059B-41CB-8A87-57CE75BC0950.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).